Somatic mutation profile of tumor specimen TCGA-XD-AAUI-01A (aliquot TCGA-XD-AAUI-01A-42D-A40W-08) from TCGA case TCGA-XD-AAUI, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.9 years (18,607 days).
Specimen TCGA-XD-AAUI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a799fdf8-998f-4385-afb8-d3acb484e1ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XD-AAUI-10A (Blood Derived Normal), aliquot TCGA-XD-AAUI-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fb06483-8b79-4346-ae8a-72346f78b8db

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Nonsense Mutation 4, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 25/197 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 30/200 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BOC | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 36/565 reads (6%) | catalogued as COSV56346860, COSV56348417; called by muse, mutect2
- CASC3 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 38/846 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99230051; called by muse, mutect2
- CDH18 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415839102, COSV99935515, COSV99938717; called by muse, mutect2
- CHAT | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 41/328 reads (13%) | catalogued as rs371470622; called by muse, mutect2, varscan2
- DDX43 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as COSV64838019; called by muse, mutect2
- DNAH9 | c.8839C>T p.R2947* | Nonsense Mutation (SNP) | VAF 17/161 reads (11%) | catalogued as rs749409414, COSV52343924; called by muse, mutect2, varscan2
- DSC1 | c.2603G>C p.R868P | Missense Mutation (SNP) | VAF 42/610 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1173352297, COSV57144048, COSV99938360; called by muse, mutect2
- F8 | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 36/662 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1046670041, CM055192, COSV64269511; called by muse, mutect2
- FBXO11 | c.554G>A p.R185H (on ENST00000403359 / NM_001190274.2; = p.R101H on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100320061; called by muse, mutect2, varscan2
- ITFG2 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99958368; called by muse, mutect2
- MOK | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 41/517 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as rs1197414796, COSV51963136; called by muse, mutect2
- MTOR | c.5358G>C p.W1786C | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1196606173, COSV100816739, COSV63869563; called by muse, mutect2
- MYCN | c.1195T>A p.S399T | Missense Mutation (SNP) | VAF 59/556 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV99808578; called by muse, mutect2, varscan2
- NUP98 | c.4799C>T p.A1600V (on ENST00000359171 / NM_001365126.1; = p.A1583V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/415 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.721); catalogued as COSV100263581; called by muse, mutect2
- PHF24 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99646321; called by muse, mutect2
- PYGL | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1053584523, COSV53584685; called by muse, mutect2
- RYR3 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 42/647 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567641089, COSV101212766; called by muse, mutect2
- RYR3 | c.11816C>A p.S3939Y (on ENST00000389232; = p.S3940Y on NM_001036.6) | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV101213265; called by muse, mutect2
- SCN9A | c.4808T>C p.F1603S (on ENST00000303354; = p.F1592S on NM_002977.3) | Missense Mutation (SNP) | VAF 46/483 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV57603618; called by muse, mutect2
- SRSF1 | c.289C>G p.R97G | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV99365500; called by muse, mutect2, varscan2
- USP9X | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 47/680 reads (7%) | catalogued as COSV61067883; called by muse, mutect2
- XIRP2 | c.5413A>C p.K1805Q (on ENST00000628543; = p.K1980Q on NM_152381.6) | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV99748142; called by muse, mutect2
- MLXIP | c.2361del p.I787Mfs*30 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel, varscan2
- ABCA9 | c.4605C>T p.I1535= | Silent (SNP) | VAF 50/356 reads (14%) | catalogued as rs1441914449, COSV100383563; called by muse, varscan2
- FLACC1 | c.798C>T p.F266= | Silent (SNP) | VAF 30/532 reads (6%) | catalogued as rs766784931, COSV53781919; called by muse, mutect2
- FRMD4A | c.1014C>T p.A338= | Silent (SNP) | VAF 45/297 reads (15%) | catalogued as COSV99198697; called by muse, mutect2, varscan2
- IL17C | c.504G>A p.S168= | Silent (SNP) | VAF 20/346 reads (6%) | catalogued as rs376824715; called by muse, mutect2
- LRP1B | c.5421C>T p.D1807= | Silent (SNP) | VAF 33/254 reads (13%) | catalogued as rs766962852, COSV67199472, COSV67287449; called by muse, mutect2, varscan2
- LRRC37B | c.2292A>G p.L764= | Silent (SNP) | VAF 72/720 reads (10%) | catalogued as COSV58955164; called by muse, mutect2
- PKD1 | c.3072C>T p.V1024= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as rs774135682, COSV99239181; called by muse, mutect2
- XIST | n.11199A>G | RNA (SNP) | VAF 46/490 reads (9%) | called by muse, mutect2
